Surgical pathology report (de-identified scan), TCGA case TCGA-FS-A1YY, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Essen, specimen TCGA-FS-A1YY-06A (Metastatic).

Prof. Dr. ...

ICD-0-3
Melanoma, NOS 8720/3
Site: abdomen, NOS 76.2
hw 7/24/11

Patient: XXXX
geb. *** **
Datum: / /

Translation of pathology report F

Sample

Gross Pathology

Cryofixed specimen with a weight of

Microscopic pathology

The H&E stained slide at hand shows an epitheloid malignant tumor with sparse amount of connective tissue. The tumor constitute approx. 90 percent of the tissue. The tumor cells show round to oval nuclei with granular chromatine. There is a high nucleo/cytoplasmatic ratio. The mitotic count is 0 mitoses per square millimetre. The tumor cells have a middle sized cytoplasm. The tumor shows a growth pattern with nest formation. Lymphocytic infiltrates compound approx. 5 percent of the tissue cells. There is no evidence of necrotic tissue. Melanophages are present.

Diagnosis: Parts of a malignant tumor, consistent with a metastasis of a melanoma.

COLF SITE - abdomen, NOS

Primary Tumor Site Discrepancy	SITE NOT STATED ON PATH	
Dual/Synchronous Tumors/Notes		

Source: NCI Genomic Data Commons file 48e79d38-ba9e-4da0-aa71-fecfd0dc051e (TCGA-FS-A1YY.A91D1EF0-6010-4536-8071-39A935247466.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).